Gene-level copy-number profile of tumor specimen TCGA-14-1823-01A from TCGA case TCGA-14-1823, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.5 years (21,384 days).
Specimen TCGA-14-1823-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.89e39087-186c-4197-9e19-64ade4e6c685.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-1823-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/28c76fa3-6a86-43cb-84bb-85dfbb819454

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,391; copy number 2: 30,810; copy number 3: 21,763; copy number 5: 3,193; copy number 6: 704; copy number 8: 229; copy number 10: 666; copy number 13: 6; copy number 57: 13; copy number 64: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-1823-01A-01D-0591-01): tumor purity 0.64, ploidy 2.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,843 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–159,233,377, 3,014 genes, copy number 5–64 (broad region; genes not listed).
- chr12:66,767–73,846,188, 1,827 genes, copy number 5–6 (broad region; genes not listed).
- chr12:73,906,940–74,049,981, 2 genes, copy number 5: AC136188.1, LINC02394.

Autosomal genes at a single copy (total copy number 1): 2,391. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
